TCGA case TCGA-69-8453 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f4f2ff3-3c02-4281-a398-b0d0955e58eb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.30; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 77.8 years (28,413 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 45 days; Days to treatment end: 157 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 413 days (1.1 years); Days to treatment end: 417 days (1.1 years); Treatment dose: 5,000 cGy; Number of fractions: 5; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed Disodium; Days to treatment start: 505 days (1.4 years); Days to treatment end: 571 days (1.6 years).
2. Recurrence of diagnosis 1 (Mucinous adenocarcinoma). Age at diagnosis: 78.7 years (28,757 days); Days to diagnosis: 344 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (6 entries)
- Days to follow up: 171 days; Disease response: With Tumor.
- Day 344 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 344 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 550 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 788 days (2.2 years); Disease response: With Tumor.
- Days to follow up: 813 days (2.2 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 52; FEV1/FVC after bronchodilator (%): 87; FEV1/FVC before bronchodilator (%): 86; FEV1 after bronchodilator (% of reference): 85; FEV1 before bronchodilator (% of reference): 85.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 12; Tobacco smoking quit year: 1974.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-69-8453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-69-8453-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 70; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 9; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
- Sample TCGA-69-8453-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-69-8453-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Mucinous (Colloid) Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; Pulmonary function test indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: carboplatinum.
- Drug treatment 3: Pharmaceutical therapy drug name: Alimta.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Stable Disease; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 813 days; disease-specific survival: no event (censored), 813 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 344 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-69-8453-01): tumor purity 0.56, ploidy 3.76, whole-genome doublings 1 (call status: snp_call).
